Somatic mutation profile of tumor specimen ALCH-B37K-TTP1-A (aliquot ALCH-B37K-TTP1-A-1-0-D-A780-36) from ALCHEMIST case ALCH-B37K, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 79.5 years (29,037 days).
Specimen ALCH-B37K-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6611f98-9f92-4dc6-8d2e-6975058cf4df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B37K-NB1-A (Blood Derived Normal), aliquot ALCH-B37K-NB1-A-1-0-D-A780-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cdb70d8-0d82-47d6-9fd2-b2e0c7e4dd81

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- METTL27 | c.167A>G p.D56G | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV52895800; called by muse, mutect2
- GLG1 | c.2234A>T p.Q745L | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); called by muse, mutect2
- OR2G3 | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.144); called by muse, mutect2
- PRKACB | c.643G>A p.G215S | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP54 | c.679-2A>T p.X227_splice | Splice Site (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- ZCCHC14 | c.12C>A p.N4K (on ENST00000268616; = p.N141K on NM_015144.3) | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.22); called by muse, mutect2
- APBA2 | c.210G>T p.G70= | Silent (SNP) | VAF 20/349 reads (6%) | called by muse, mutect2
- FOXA1 | c.363G>T p.A121= | Silent (SNP) | VAF 11/229 reads (5%) | catalogued as COSV99163742; called by muse, mutect2
- ZFPM1 | c.1089C>G p.L363= | Silent (SNP) | VAF 17/222 reads (8%) | called by muse, mutect2
- TFAP2A | c.*2G>T | 3'UTR (SNP) | VAF 16/135 reads (12%) | called by mutect2, varscan2
